Somatic mutation profile of tumor specimen TCGA-BQ-5885-01A (aliquot TCGA-BQ-5885-01A-11D-1589-08) from TCGA case TCGA-BQ-5885, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 63.4 years (23,173 days).
Specimen TCGA-BQ-5885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b4e1735-843c-4b18-bbb2-3c83783a7a2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5885-11A (Solid Tissue Normal), aliquot TCGA-BQ-5885-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cd5cedb-0793-4d3a-97eb-f289e233e2e0

The open-access MAF lists 118 somatic variants for this specimen: 98 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 17, Frame Shift Del 8, Nonsense Mutation 5, Splice Site 4, Intron 3, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD1 | c.1270A>G p.T424A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs1325332964, COSV56645655; called by muse, mutect2
- AGTR2 | c.91T>G p.S31A | Missense Mutation (SNP) | VAF 60/92 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV64156794; called by muse, mutect2, varscan2
- ARHGAP39 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as rs1469426462, COSV52773947; called by muse, mutect2, varscan2
- ARHGEF7 | c.735G>A p.E245= (on ENST00000375741 / NM_001113511.2; = p.E67= on NM_003899.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 73/127 reads (57%) | catalogued as COSV54548037; called by muse, mutect2, varscan2
- ATF7 | c.300T>A p.A100= (on ENST00000548446 / NM_001366555.2; = p.A89= on NM_006856.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 16/46 reads (35%) | catalogued as COSV60645202; called by muse, varscan2
- BCL9L | c.2766T>G p.N922K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV52687411; called by muse, mutect2, varscan2
- C3AR1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV50821007; called by muse, mutect2, varscan2
- CAD | c.135C>A p.Y45* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV53029936; called by muse, mutect2, varscan2
- CCR5 | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1349880297, COSV52752447; called by muse, mutect2, varscan2
- CELSR1 | c.5191G>A p.A1731T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV53090344; called by muse, mutect2
- CEP85 | c.1955A>T p.H652L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV53331356; called by muse, mutect2, varscan2
- CNNM2 | c.1071G>T p.E357D | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63996253; called by muse, mutect2, varscan2
- CNTN5 | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV54336767; called by muse, mutect2
- COX10 | c.142A>C p.I48L | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV55407255; called by muse, mutect2, varscan2
- CRYBG1 | c.5182C>A p.H1728N | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64813533; called by muse, mutect2, varscan2
- CUL3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100024274, COSV52367909; called by muse, mutect2, varscan2
- CYB5RL | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as COSV55278213; called by muse, mutect2, varscan2
- DDX39B | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV63331699; called by muse, mutect2, varscan2
- DENND5B | c.2050A>G p.K684E | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV60905920; called by muse, varscan2
- DST | c.20264T>C p.L6755S (on ENST00000361203 / NM_001374722.1; = p.L4452S on NM_015548.5) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55029578; called by muse, mutect2, varscan2
- EID3 | c.507T>A p.H169Q | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61600488; called by muse, mutect2, varscan2
- ELAPOR1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64040881; called by muse, mutect2, varscan2
- EPPK1 | c.3172C>A p.L1058I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.033); catalogued as COSV73262034; called by muse, mutect2, varscan2
- FAU | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs3202210, COSV54195558; called by muse, mutect2, varscan2
- FMO4 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV63001618; called by muse, mutect2, varscan2
- FMO4 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV63001622; called by muse, mutect2, varscan2
- GATAD2A | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV53073383; called by muse, mutect2, varscan2
- GBF1 | c.3556C>A p.L1186I (on ENST00000369983 / NM_001377137.1; = p.L1185I on NM_004193.3) | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as COSV64147380; called by muse, mutect2, varscan2
- GOLPH3 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.925); catalogued as COSV54061901; called by muse, mutect2, varscan2
- GPBP1 | c.901T>G p.F301V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV53313386; called by muse, mutect2, varscan2
- HEATR1 | c.3193G>A p.G1065R | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.389); catalogued as COSV63982321; called by muse, mutect2, varscan2
- HEATR1 | c.1732A>G p.I578V | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1558189046, COSV63982324; called by muse, mutect2, varscan2
- IL4R | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | catalogued as COSV50156184; called by muse, mutect2, varscan2
- LMTK2 | c.3943G>C p.E1315Q | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.608); catalogued as rs199600469, COSV52000457; called by muse, mutect2, varscan2
- LNPEP | c.1229T>A p.I410N | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51479785; called by muse, mutect2, varscan2
- LRBA | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV63960372; called by muse, mutect2, varscan2
- LRP1B | c.1223T>A p.I408N | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV101261243, COSV67252619; called by muse, mutect2, varscan2
- LRP2 | c.5246T>C p.I1749T | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV55565068; called by muse, mutect2, varscan2
- MMP21 | c.1447A>C p.N483H | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV61765350; called by muse, mutect2, varscan2
- MST1 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56535637; called by muse, varscan2
- NCSTN | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1485930779, COSV54189977; called by muse, varscan2
- NIBAN1 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62286616; called by muse, mutect2, varscan2
- NKD1 | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.328); catalogued as COSV51692977; called by muse, mutect2, varscan2
- OR2M3 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71758928; called by muse, mutect2
- OR8D1 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV63442803; called by muse, mutect2
- OTOP1 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56395274; called by muse, mutect2, varscan2
- PAK4 | c.1397G>T p.S466I | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV58946046; called by muse, mutect2, varscan2
- PAPPA | c.2369C>G p.P790R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs759094445, COSV60288653, COSV60289041; called by muse, mutect2, varscan2
- PCDHA9 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV65329955; called by muse, mutect2, varscan2
- PCDHGA9 | c.2201G>C p.G734A | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV53995779; called by muse, mutect2, varscan2
- PCDHGC3 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs747509171, COSV52760375; called by muse, mutect2, varscan2
- PEX1 | c.3439-2A>G p.X1147_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV50406682; called by muse, mutect2, varscan2
- PHF20L1 | c.2580G>C p.E860D | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55195697; called by muse, mutect2, varscan2
- PHRF1 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV52759642; called by muse, mutect2, varscan2
- PI4K2A | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1386914901, COSV65701980; called by muse, mutect2, varscan2
- PLK4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV54636380, COSV54638595; called by muse, mutect2, varscan2
- PRELID3B | c.33-1G>A p.X11_splice | Splice Site (SNP) | VAF 56/140 reads (40%) | catalogued as COSV63505000; called by muse, mutect2, varscan2
- PRKDC | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 56/178 reads (31%) | catalogued as COSV58059167; called by muse, mutect2, varscan2
- PSMA8 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV57603977; called by muse, mutect2, varscan2
- QTRT2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 100/255 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs199551955, COSV55561024; called by muse, mutect2, varscan2
- RTN4 | c.1722A>T p.E574D | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58271426; called by muse, mutect2, varscan2
- RTN4 | c.1721A>C p.E574A | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58271445; called by muse, mutect2, varscan2
- SAV1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100220828; called by mutect2, varscan2
- SEMA4F | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60283920, COSV60284482; called by muse, mutect2, varscan2
- SF3A1 | c.905A>T p.E302V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53170322; called by muse, mutect2, varscan2
- SIRPB1 | c.1031A>T p.Y344F | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53539963; called by muse, mutect2, varscan2
- SLC35D3 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV59378118; called by muse, mutect2, varscan2
- SLC7A2 | c.377-1G>T p.X126_splice (on ENST00000494857 / NM_001370338.1; = p.X166_splice on NM_003046.6) | Splice Site (SNP) | VAF 39/121 reads (32%) | catalogued as COSV50264630; called by muse, mutect2, varscan2
- SMC5 | c.995A>T p.K332M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63194565; called by muse, mutect2, varscan2
- SMG1 | c.8888C>A p.A2963E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67173645; called by muse, mutect2, varscan2
- SMG1 | c.8887G>A p.A2963T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV67173653; called by muse, mutect2, varscan2
- SORCS1 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53884447; called by muse, mutect2, varscan2
- SRGAP1 | c.2813C>A p.S938Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV61901172, COSV61902036; called by muse, mutect2, varscan2
- TBATA | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV54720484; called by muse, mutect2, varscan2
- TEX19 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61017881; called by muse, mutect2, varscan2
- TMEM177 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV55609311; called by muse, mutect2, varscan2
- TNFSF10 | c.724A>T p.I242F | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53843948; called by muse, mutect2, varscan2
- TRIM23 | c.884T>A p.L295Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51553378; called by muse, mutect2, varscan2
- TRIM36 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201228593, COSV56691813; called by muse, mutect2
- TRPM8 | c.491T>A p.I164N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61223138; called by muse, mutect2, varscan2
- TRPV3 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1265973608, COSV56791678; called by muse, mutect2, varscan2
- USP40 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV52478958, COSV52480289; called by muse, varscan2
- USP54 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1305790310, COSV60445550; called by muse, mutect2, varscan2
- YLPM1 | c.761dup p.G255Wfs*3 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs760065689; called by mutect2, varscan2
- ZBBX | c.233A>C p.Q78P | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs778298074, COSV56796284; called by muse, mutect2, varscan2
- ZNF57 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60984060; called by muse, mutect2, varscan2
- ZNF846 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67412360; called by muse, mutect2, varscan2
- ADAMDEC1 | c.751del p.L251Yfs*4 | Frame Shift Del (DEL) | VAF 48/163 reads (29%) | called by mutect2, pindel, varscan2
- DMTF1 | c.440_442+1del p.X147_splice | Splice Site (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- EPHA4 | c.843del p.Y281* | Frame Shift Del (DEL) | VAF 46/92 reads (50%) | called by mutect2, pindel, varscan2
- FAT1 | c.7449_7452del p.I2483Mfs*18 | Frame Shift Del (DEL) | VAF 79/361 reads (22%) | called by mutect2, pindel, varscan2
- JMJD1C | c.5147del p.L1716Yfs*9 | Frame Shift Del (DEL) | VAF 28/91 reads (31%) | called by mutect2, pindel, varscan2
- KLHL4 | c.1525A>G p.M509V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, varscan2
- MST1 | c.80_83dup p.G29Lfs*12 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- SYBU | c.1364del p.D455Afs*19 (on ENST00000276646 / NM_001099754.2; = p.D454Afs*19 on NM_017786.6) | Frame Shift Del (DEL) | VAF 33/120 reads (28%) | called by mutect2, pindel, varscan2
- TPST1 | c.531_552del p.K178Mfs*9 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel
- USP34 | c.5427del p.G1810Dfs*5 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- ZNF502 | c.75del p.K25Nfs*16 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | called by mutect2, pindel, varscan2
- AKAP9 | c.2637A>G p.E879= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62353254; called by muse, mutect2, varscan2
- ALMS1 | c.7023T>C p.N2341= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1201697946, COSV52516568; called by muse, mutect2, varscan2
- ANKRD50 | c.1645T>C p.L549= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs767138586, COSV72386011; called by muse, mutect2, varscan2
- APOBEC3G | c.987C>G p.A329= | Silent (SNP) | VAF 55/189 reads (29%) | catalogued as COSV68470626; called by muse, mutect2, varscan2
- ATP2B2 | c.2451C>T p.L817= (on ENST00000352432; = p.L783= on NM_001683.5) | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV59503573; called by muse, mutect2, varscan2
- CD180 | c.1963A>C p.R655= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV56519115; called by muse, mutect2, varscan2
- DGAT2 | c.999C>T p.P333= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV57176892; called by muse, mutect2, varscan2
- EBF2 | c.1495C>T p.L499= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV68779361; called by muse, mutect2, varscan2
- FYCO1 | c.858G>A p.E286= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1025735214, COSV56114116, COSV56118084; called by muse, mutect2, varscan2
- LRRC41 | c.639A>C p.S213= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV58441258; called by muse, mutect2, varscan2
- OR8B8 | c.63G>A p.P21= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs771571997, COSV60143720; called by muse, mutect2, varscan2
- OSCP1 | c.48G>A p.E16= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV52487422; called by muse, mutect2, varscan2
- OTOP1 | c.1554G>A p.E518= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV56395282; called by muse, mutect2, varscan2
- SDAD1 | c.1965G>A p.R655= | Silent (SNP) | VAF 94/282 reads (33%) | catalogued as COSV62403448; called by muse, mutect2, varscan2
- TAX1BP1 | c.1884T>C p.N628= | Silent (SNP) | VAF 93/272 reads (34%) | catalogued as rs753091132, COSV55293071, COSV55295334; called by muse, mutect2, varscan2
- TBC1D8 | c.459C>T p.F153= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV65214647; called by muse, mutect2, varscan2
- TBX4 | c.444G>C p.L148= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV53608736; called by muse, mutect2, varscan2
- CNEP1R1 | c.25+349G>A | Intron (SNP) | VAF 4/66 reads (6%) | catalogued as COSV66697091; called by muse, mutect2
- MGA | c.1065-4406T>A | Intron (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99580698; called by muse, mutect2, varscan2
- SND1 | c.1779+6735C>A | Intron (SNP) | VAF 90/293 reads (31%) | catalogued as COSV100690772, COSV61241061; called by muse, mutect2, varscan2
